Somatic mutation profile of tumor specimen 0DH293 from CCDI case PBBTVK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.2 years (4,092 days).
Specimen 0DH293: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4c7d3f5-e1f5-44f1-bf74-53da4488bd97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH27J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a93c2143-7ba7-4138-b004-2f74395abef5

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLVCR2 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 192/1416 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.029); catalogued as rs763752990; called by muse, mutect2, varscan2
- LRRC43 | c.1574G>A p.G525E | Missense Mutation (SNP) | VAF 103/786 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLEC16A | c.2526C>T p.L842= | Silent (SNP) | VAF 90/568 reads (16%) | catalogued as rs200280529; called by muse, mutect2, varscan2
- FGR | c.399G>A p.V133= | Silent (SNP) | VAF 125/886 reads (14%) | called by muse, mutect2, varscan2
